Somatic mutation profile of tumor specimen ALCH-B029-TTP1-A (aliquot ALCH-B029-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B029, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 48.0 years (17,539 days).
Specimen ALCH-B029-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5505d74-5f7f-481b-ac22-9962ab08d639.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B029-NB1-A (Blood Derived Normal), aliquot ALCH-B029-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8f4734-3a27-4122-9fe1-dce739713b5c

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 23/295 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- GPR179 | c.1468C>T p.R490W (on ENST00000621958; = p.R489W on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1231986529; called by muse, mutect2
- MAPK15 | c.1205-4A>C | Splice Region (SNP) | VAF 11/194 reads (6%) | catalogued as rs782312051; called by muse, mutect2
- DYNC2I1 | c.2770A>T p.I924L | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.029); called by muse, mutect2
- FGF12 | c.26T>G p.L9W | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- VAMP7 | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- CCDC168 | c.3051A>G p.L1017= | Silent (SNP) | VAF 34/257 reads (13%) | called by muse, mutect2, varscan2
- SRPX2 | c.99G>A p.P33= | Silent (SNP) | VAF 46/656 reads (7%) | catalogued as rs766670891; called by muse, mutect2
- TCIRG1 | c.2295G>A p.E765= | Silent (SNP) | VAF 25/361 reads (7%) | catalogued as rs775393308; called by muse, mutect2
- UMODL1 | c.3603G>A p.R1201= (on ENST00000408910 / NM_001004416.2; = p.R1329= on NM_173568.3) | Silent (SNP) | VAF 18/476 reads (4%) | catalogued as COSV101252482; called by muse, mutect2
- ZNF467 | chr7:149776496 G>C | 5'Flank (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
